Gene-level copy-number profile of tumor specimen TCGA-HT-A4DS-01A from TCGA case TCGA-HT-A4DS, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 55.6 years (20,296 days).
Specimen TCGA-HT-A4DS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.668e4178-c124-44fd-9879-b1817b313fad.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-A4DS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/04b06779-bdb4-46b5-8723-9256d08b56e1

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 43,865; copy number 2: 15,869; copy number 3: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-A4DS-01A-11D-A26L-01): tumor purity 0.8, ploidy 2.13, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,780,340–50,974,634, 3 genes: PHBP12, MRPS6P2, CDKN2C.
- chr9:20,658,309–23,682,662, 69 genes (broad region; genes not listed).
- chr17:63,193,930–63,339,053, 3 genes: AC015923.1, AC005828.2, AC005828.7.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 10 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:82,603,529–82,817,741, 5 genes, copy number 3: AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3.
- chr11:82,835,509–82,837,222, 1 gene, copy number 3: EIF2S2P6.
- chr11:128,880,325–128,943,399, 4 genes, copy number 3: AP000920.1, KCNJ5, C11orf45, TP53AIP1.

Autosomal genes at a single copy (total copy number 1): 41,444. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
